Gene-level copy-number profile of tumor specimen HTMCP-01-20-00779-01A from CGCI case HTMCP-01-20-00779, project CGCI-HTMCP-DLBCL (HIV+ Tumor Molecular Characterization Project - Diffuse Large B-Cell Lymphoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Primary diffuse large B-cell lymphoma of the CNS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 51.8 years (18,925 days).
Specimen HTMCP-01-20-00779-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e1d9a1da-ad70-4d4f-b267-b2b956b2b582.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-01-20-00779-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,724 have no estimate.
https://portal.gdc.cancer.gov/files/85a220ba-1482-4359-bf1d-3463a849818d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 28; copy number 1: 3,126; copy number 2: 55,087; copy number 3: 596; copy number 4: 35; copy number 5: 8; copy number 6: 4; copy number 7: 3; copy number 9: 1; copy number 11: 1; copy number 18: 9; copy number 24: 1.

Homozygous deletions (total copy number 0; autosomes only): 28 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr22:22,738,944–22,755,797, 3 genes (within-gene range 0–1): IGLV3-17, IGLV3-16, IGLV3-15.
- chr22:22,762,294–22,905,025, 25 genes (within-gene range 0–1): IGLV3-13, IGLV3-12, AC244157.2, IGLV2-11, AC245028.3, IGLV3-10, AC245028.1, IGLV3-9, IGLV2-8, MIR650, AC245028.2, IGLV3-7, IGLV3-6, IGLV2-5, IGLV3-4, IGLV4-3, IGLV3-2, IGLV3-1, MIR5571, IGLL5, IGLJ1, IGLC1, IGLJ2, IGLC2, IGLJ3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 27 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:121,573,946–121,580,524, 1 gene, copy number 5: LINC01691.
- chr2:89,297,264–89,600,680, 5 genes, copy number 5: IGKV1-37, IGKV2-38, IGKV1-39, IGKV2-40, 5S_rRNA.
- chr9:40,883,634–40,883,763, 1 gene, copy number 5: AL353626.2.
- chr11:48,880,111–48,908,946, 4 genes, copy number 6: AC027369.6, AC027369.3, AC027369.4, AC027369.5.
- chr15:22,160,431–22,160,868, 1 gene, copy number 24: IGHV1OR15-1.
- chr16:32,715,931–32,788,944, 8 genes, copy number 18: AC138907.6, ABHD17AP7, AC138907.2, AC138907.4, HERC2P5, AC138907.8, AC138907.9, AC138907.10.
- chr16:32,882,586–32,888,874, 1 gene, copy number 11 (within-gene range 1–11): AC142086.1.
- chr16:33,533,816–33,570,935, 4 genes, copy number 7–18: AC136944.1, AC136944.2, AC136944.4, AC136944.3.
- chr17:75,431,990–75,432,087, 1 gene, copy number 5: Y_RNA.
- chr21:43,092,956–43,107,570, 1 gene, copy number 9: U2AF1.

Autosomal genes at a single copy (total copy number 1): 288. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
